Surgical pathology report (de-identified scan), TCGA case TCGA-Y8-A8S1, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Spectrum Health, specimen TCGA-Y8-A8S1-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

male with renal lesion_

Research Dx

Left lower pole renal mass, partial nephrectomy:
Papillary carcinoma, Type 2, cystic.
Small cortical adenoma.

ICD-O-3
Carcinoma, papillary renal
cell 8260/3
Site: ① Kidney NOS
C64.9
JW 1/17/14

CASE SUMMARY FOR NEPHRECTOMY FOR RENAL CELL CARCINOMA:

Procedure: Partial nephrectomy

Specimen laterality: Left

Tumor site: Lower pole of kidney

Tumor size: 2.3 cm

Tumor focality: Unifocal

Macroscopic extent of tumor: Confined to kidney

Histologic type: Papillary carcinoma Type 2

Sarcomatoid features: Absent

Tumor necrosis: Absent

Histologic grade (Fuhrman Nuclear Grade): 3/4

Microscopic tumor extension: Confined to kidney

Margins: Negative (Parenchymal)

Lymphovascular invasion: Not identified

Pathologic staging (pTNM):

Primary tumor: pT1a, 4 cm or less, limited to kidney

Regional lymph nodes: pNX, none sampled

Distant metastasis: pMna

Pathologic findings in nonneoplastic kidney: Scattered sclerotic glomeruli and interstitial nephritis

Other tumors and/or tumor-like lesions: small cortical adenoma

AJCC Staging (7th edition) pT1a pNX pMna

Research QC

Tumor T1:

60% tumor nuclei

40% necrosis

0% normal

Normal N1:

100% nonneoplastic kidney

Research Specimen

—

Specimen Process Time

Blood draw time:

Plasma frozen time

Serum frozen time

Buffy coat frozen time

Cold ischemia start time:

Formalin fixation start time:

Total cold ischemia time:

[page 2 of 2]
Formalin fixation stopped time

Total formalin fixation time

Specimen Weight

Normal

1-115 mg

Tumor

1-174 mg

Specimen Size

Plasma x 3

Serum x 2

Buffy coat x 1

Cryovials x 2

Normal x 1

Tumor x 1

FFPE x2

Normal x 1

Tumor x 1

Study

Patient Consent

Yes

Source: NCI Genomic Data Commons file 36f9161a-cf21-404c-939d-c4e350029793 (TCGA-Y8-A8S1.E72FCA55-BD25-4855-9B25-039FD1037722.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).